CCDI case PBCICZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/7f46f745-6b3d-4911-8142-e47b8b613cc4

Demographics
Sex at birth: male; Race: white.

Biospecimens (2 samples)
- Sample 0DSJYA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSJYK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
